Gene-level copy-number profile of tumor specimen TCGA-BT-A20N-01A from TCGA case TCGA-BT-A20N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 72.4 years (26,456 days).
Specimen TCGA-BT-A20N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.fcf935c6-5fb5-4969-8607-cac97bc22466.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A20N-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 820 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6110aca0-59b1-4549-a489-3bb3a945fd0d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 513; copy number 2: 6,991; copy number 3: 15,541; copy number 4: 12,805; copy number 5: 9,218; copy number 6: 6,270; copy number 7: 2,743; copy number 8: 3,435; copy number 9: 1,406; copy number 10: 298; copy number 11: 85; copy number 12: 43; copy number 13: 82; copy number 14: 36; copy number 17: 12; copy number 19: 109; copy number 21: 119; copy number 22: 39; copy number 25: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A20N-01A-11D-A14V-01): tumor purity 0.72, ploidy 1.61, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:226,835,581–228,841,689, 36 genes (within-gene range 0–2): RHBDD1, AC073149.1, COL4A4, COL4A3, MFF-DT, MFF, TM4SF20, SCYGR1, MIR5703, AGFG1, SCYGR9, SCYGR2, SCYGR10, C2orf83, SCYGR3, AC064853.1, SCYGR4, SCYGR5, SLC19A3, SCYGR6, SCYGR7, SCYGR8, RNA5SP121, SNRPGP8, AC073065.1, CCL20, TDGF1P2, DAW1, AC073065.2, SPHKAP, RNU6-624P, SNF8P1, AC009410.1, LINC01807, AC012070.1, RPL7L1P10.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 8,429 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–197,223,255, 1,433 genes, copy number 7–10 (broad region; genes not listed).
- chr1:218,285,293–227,947,932, 204 genes, copy number 8 (broad region; genes not listed).
- chr1:238,238,943–248,919,946, 259 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr3:11,745–18,445,588, 290 genes, copy number 7–8 (broad region; genes not listed).
- chr3:18,538,673–18,539,899, 1 gene, copy number 7: RAD23BP1.
- chr3:80,442,081–81,208,914, 6 genes, copy number 7: AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2.
- chr3:128,538,020–132,874,223, 114 genes, copy number 7 (broad region; genes not listed).
- chr3:133,038,391–182,368,256, 748 genes, copy number 7–8 (within-gene range 2–8) (broad region; genes not listed).
- chr3:187,217,282–198,222,513, 239 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr5:6,765,891–54,310,582, 631 genes, copy number 7–25 (within-gene range 3–25) (broad region; genes not listed).
- chr6:167,607–2,245,605, 34 genes, copy number 7: AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1.
- chr6:2,341,450–2,341,711, 1 gene, copy number 7: HMGN2P28.
- chr6:3,268,962–15,663,058, 214 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr6:55,434,373–60,546,660, 38 genes, copy number 7 (within-gene range 4–7): HMGCLL1, AL590290.1, BMP5, NPM1P36, COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1, AC244258.1.
- chr7:70,972–57,837,046, 1,078 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr8:150,584–1,801,711, 34 genes, copy number 8: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1.
- chr8:1,801,125–1,817,307, 3 genes, copy number 8: MIR3674, AC100810.7, MIR596.
- chr8:2,033,508–16,567,490, 352 genes, copy number 8–10 (broad region; genes not listed).
- chr8:16,604,255–16,664,879, 1 gene, copy number 10: AC011586.1.
- chr8:124,550,784–138,497,261, 165 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr9:36,336,396–36,677,683, 2 genes, copy number 7: RNF38, MELK.
- chr9:37,322,259–37,592,604, 13 genes, copy number 8: Y_RNA, RNU6-677P, LINC01627, GRHPR, CHCHD4P3, ZBTB5, KCTD9P3, POLR1E, AL158156.1, AL513165.1, FBXO10, AL513165.2, TOMM5.
- chr10:44,712–11,336,675, 192 genes, copy number 8–10 (within-gene range 6–10) (broad region; genes not listed).
- chr10:19,048,801–19,790,401, 1 gene, copy number 8 (within-gene range 6–8): MALRD1.
- chr10:19,489,101–36,626,138, 298 genes, copy number 7–8 (broad region; genes not listed).
- chr10:57,304,479–61,001,440, 37 genes, copy number 8 (within-gene range 4–8): MIR3924, AL731534.1, AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP, RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P.
- chr11:74,493,851–81,556,425, 144 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr11:81,842,435–81,987,813, 3 genes, copy number 7: AP002802.2, MIR4300, AP002802.1.
- chr11:134,032,216–135,075,908, 26 genes, copy number 7: LINC02731, AP000911.1, JAM3, PTP4A2P2, NCAPD3, AP001775.1, AP001775.2, VPS26B, THYN1, ACAD8, GLB1L3, AP000859.1, GLB1L2, B3GAT1, B3GAT1-DT, AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.
- chr12:66,767–34,219,246, 849 genes, copy number 7 (broad region; genes not listed).
- chr12:40,692,439–41,072,415, 1 gene, copy number 8 (within-gene range 6–8): CNTN1.
- chr12:40,978,744–45,216,041, 60 genes, copy number 8–11 (within-gene range 4–11): AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1.
- chr13:73,399,031–73,408,352, 2 genes, copy number 11: AL162376.1, MARK2P12.
- chr14:82,429,872–87,332,390, 32 genes, copy number 7–11: Metazoa_SRP, LINC02301, ENSAP2, AL355095.1, AL359238.1, AL162872.1, RNU7-51P, RNU6ATAC28P, AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316, AL161753.1, LINC02309, LINC01148, AL358292.1, AL352955.1, AL157688.1.
- chr16:70,802,084–71,230,722, 4 genes, copy number 8 (within-gene range 6–8): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr16:81,961,926–83,819,737, 26 genes, copy number 7: RN7SKP176, AC092142.2, SDR42E1, HSD17B2, AC092142.1, MTCYBP28, MPHOSPH6, AC138304.1, RN7SKP190, AC009117.1, AC009117.2, CDH13, MIR8058, AC099506.2, AC099506.1, AC099506.3, RN7SL134P, AC125793.1, AC009142.1, MIR3182, AC009063.3, AC009063.4, AC009063.2, AC009063.1, AC009119.1, HSBP1.
- chr19:27,638,483–40,094,406, 464 genes, copy number 8 (broad region; genes not listed).
- chr21:31,038,159–46,665,124, 430 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
